Somatic mutation profile of tumor specimen 0DG5AL from CCDI case PBBRZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 15.0 years (5,495 days).
Specimen 0DG5AL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69679c75-ece9-4198-a86a-97e47ff941f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG5AA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d91c9b6e-cd45-4bcc-9fcf-6e372d48ad4b

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 129/483 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- MTBP | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs376379256; called by muse, mutect2
- OTUD1 | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752718054; called by muse, mutect2
- KIF14 | c.2071A>C p.T691P | Missense Mutation (SNP) | VAF 29/626 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE2T | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 57/532 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF710 | c.1645T>C p.C549R | Missense Mutation (SNP) | VAF 42/553 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCL11A | c.1569C>T p.H523= (on ENST00000335712 / NM_001365609.1; = p.H557= on NM_018014.4) | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- DCTD | c.354C>T p.I118= | Silent (SNP) | VAF 19/602 reads (3%) | catalogued as COSV63866997; called by muse, mutect2
- SBK3 | c.321C>T p.P107= | Silent (SNP) | VAF 26/496 reads (5%) | called by muse, mutect2
- PMPCB | c.*284C>T | 3'UTR (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- QPCT | c.-90G>C | 5'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
